Somatic mutation profile of tumor specimen TCGA-SP-A6QC-01A (aliquot TCGA-SP-A6QC-01A-11D-A35I-08) from TCGA case TCGA-SP-A6QC, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 46.2 years (16,891 days).
Specimen TCGA-SP-A6QC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d39c6bcf-f48a-499b-9f22-42b6dca5f9af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SP-A6QC-10A (Blood Derived Normal), aliquot TCGA-SP-A6QC-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3002f9d1-8079-4dc3-94a6-8956ce60096b

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 8, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXO28 | c.532T>C p.Y178H | Missense Mutation (SNP) | VAF 49/94 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV64799562, COSV64800547; called by muse, mutect2, varscan2
- GAD1 | c.1370G>A p.R457H | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1190356035; called by muse, mutect2
- LCE1E | c.49A>C p.T17P | Missense Mutation (SNP) | VAF 77/180 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs773161688, COSV64219634; called by muse, mutect2, varscan2
- VIT | c.1882G>A p.V628I (on ENST00000389975 / NM_001177969.1; = p.V643I on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs368417581; called by muse, mutect2, varscan2
- IPO8 | c.2329G>A p.E777K | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- OXTR | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SUSD4 | c.551T>G p.L184R | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SUSD4 | c.550C>A p.L184I | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM214A | c.1044C>T p.N348= | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as rs1351698596; called by muse, mutect2
- PDZD2 | c.2097G>C p.G699= | Silent (SNP) | VAF 10/39 reads (26%) | called by muse, mutect2, varscan2
